CGCI case HTMCP-02-03-01007 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e0edc1ed-7884-46b2-9d1a-6e9fc97bca58

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.5 years (19,891 days); Year of diagnosis: 2010; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,409 days (6.6 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 4.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 1,217 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 2,409 days (6.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -4,171.

Other clinical attributes
- Day -4,171: Risk factors: HIV/AIDS.
- Day -4,171: Comorbidities: HIV/AIDS.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Weight: 84 kg; Height: 167.64 cm; BMI: 29.9; CD4 count: 81000; HIV viral load: 388.
- Day 0: Immunosuppressive treatment type: Azathioprine; Risk factor treatment: Yes.
- Day 0: Risk factors: Hepatitis C Infection.
- Day 0: Cdc hiv risk factors: Intravenous Drug User.
- Day 1,217: Nadir CD4 count: 300.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 20.

Biospecimens (3 samples)
- Sample HTMCP-02-03-01007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01007-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-03-01007-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Tumor status: Tumor free; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Complete Remission/Response; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Lower lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1999; Cdc HIV risk group: IV drug user; History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Fine needle aspiration biopsy; Days from index date to tumor sample procurement: -12.
